Somatic mutation profile of tumor specimen TCGA-DX-A6BA-01A (aliquot TCGA-DX-A6BA-01A-11D-A307-09) from TCGA case TCGA-DX-A6BA, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 53.3 years (19,455 days).
Specimen TCGA-DX-A6BA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f568360-6837-4686-a02c-b49926b2c849.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6BA-10A (Blood Derived Normal), aliquot TCGA-DX-A6BA-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e19b0575-325e-43bf-a2fa-5b32e74008b7

The open-access MAF lists 48 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 31, Silent 9, Frame Shift Del 3, Splice Region 2, In Frame Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011448.1 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs137852869, CM055453, COSV99389320; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 50/65 reads (77%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA2 | c.3646G>A p.D1216N (on ENST00000614293; = p.D1186N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/185 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99688552; called by muse, mutect2, varscan2
- ABCA5 | c.2969A>T p.Y990F | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV101201301; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3685A>C p.K1229Q | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99721500; called by muse, mutect2, varscan2
- ANKRD30A | c.2769G>C p.W923C (on ENST00000611781; = p.W867C on NM_052997.2) | Missense Mutation (SNP) | VAF 139/165 reads (84%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as rs775101938, COSV100654541; called by muse, mutect2, varscan2
- ANO4 | c.1039A>T p.I347F (on ENST00000392977 / NM_001286615.2; = p.I312F on NM_178826.4) | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153978; called by muse, mutect2, varscan2
- BOLL | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV99987474; called by muse, mutect2, varscan2
- C3 | c.4278C>G p.D1426E | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as COSV55580883; called by muse, mutect2, varscan2
- CAPN9 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201859022, COSV99681187; called by muse, mutect2, varscan2
- CAPS2 | c.1654T>A p.S552T | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100158373; called by muse, mutect2, varscan2
- CHD6 | c.7769C>G p.P2590R | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100951394; called by muse, mutect2, varscan2
- COL4A3 | c.2767G>A p.V923I | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs917860017, COSV100516886; called by muse, mutect2, varscan2
- COL6A1 | c.1919A>G p.K640R | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.223); catalogued as COSV100720491; called by muse, mutect2, varscan2
- CYP4F2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs371325087; called by muse, mutect2, varscan2
- EWSR1 | c.1316A>T p.K439I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.461); catalogued as COSV100132171; called by muse, mutect2
- FMO2 | c.1376T>A p.L459Q | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99269366; called by muse, mutect2, varscan2
- GGH | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1417608098, COSV99479053; called by muse, mutect2, varscan2
- IGF2BP1 | c.1259T>C p.I420T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99289170; called by muse, mutect2, varscan2
- INO80 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100732098; called by muse, mutect2
- JOSD1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99320223; called by muse, mutect2, varscan2
- KCNG4 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 78/89 reads (88%) | SIFT tolerated (0.19); PolyPhen benign (0.312); catalogued as rs771376159, COSV100377123; called by muse, mutect2, varscan2
- KIAA1210 | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV101274432; called by muse, mutect2, varscan2
- KREMEN2 | c.270T>C p.R90= | Splice Region (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99567047; called by muse, mutect2, varscan2
- LAMB3 | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99152275; called by muse, mutect2, varscan2
- OR9A4 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as rs781894587, COSV101516569, COSV71885963, COSV71886114; called by muse, mutect2, varscan2
- PCDH15 | c.1260G>C p.L420F | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100228480; called by muse, mutect2, varscan2
- PNMA5 | c.422A>C p.Q141P | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV100721726; called by muse, mutect2, varscan2
- RICTOR | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV99705823; called by muse, mutect2
- RINL | c.743A>G p.D248G (on ENST00000591812 / NM_001195833.2; = p.D134G on NM_198445.4) | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV100531390; called by muse, mutect2, varscan2
- SALL3 | c.3250G>A p.V1084I | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs772346072, COSV73305953, COSV73306033; called by muse, mutect2, varscan2
- TCAIM | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.666); catalogued as COSV100703438; called by muse, mutect2, varscan2
- ZPBP2 | c.224C>G p.P75R (on ENST00000348931 / NM_199321.3; = p.P53R on NM_198844.3) | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100818573; called by muse, mutect2
- AKNAD1 | c.443_445dup p.I148dup | In Frame Ins (INS) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- EIF4G3 | c.3161_3170del p.K1054Sfs*16 | Frame Shift Del (DEL) | VAF 57/156 reads (37%) | called by mutect2, pindel, varscan2
- FGD5 | c.1065del p.S356Lfs*17 | Frame Shift Del (DEL) | VAF 56/134 reads (42%) | called by mutect2, pindel, varscan2
- PRKCE | c.1828_1854del p.D610_S618del | In Frame Del (DEL) | VAF 44/59 reads (75%) | called by mutect2, pindel, varscan2
- TBC1D29P | n.2575+1del | Splice Region (DEL) | VAF 23/236 reads (10%) | called by mutect2, pindel, varscan2
- TEK | c.255del p.V86Lfs*31 | Frame Shift Del (DEL) | VAF 36/172 reads (21%) | called by mutect2, pindel, varscan2
- ATP10D | c.2634T>A p.S878= | Silent (SNP) | VAF 69/185 reads (37%) | catalogued as COSV99905832, COSV99906250; called by muse, mutect2, varscan2
- FNDC1 | c.1221A>T p.G407= | Silent (SNP) | VAF 66/172 reads (38%) | catalogued as COSV99797122; called by muse, mutect2, varscan2
- ITIH6 | c.1581T>C p.D527= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99514086; called by muse, mutect2, varscan2
- KIFC1 | c.867T>C p.R289= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100997145; called by muse, mutect2, varscan2
- KLRB1 | c.171G>C p.G57= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV99987354; called by muse, mutect2, varscan2
- NCOR1 | c.2271G>A p.T757= | Silent (SNP) | VAF 76/265 reads (29%) | catalogued as rs781757424, COSV51961413; called by muse, mutect2, varscan2
- PCDHB15 | c.1584G>A p.E528= | Silent (SNP) | VAF 209/448 reads (47%) | catalogued as rs781808162, COSV99179270; called by muse, mutect2, varscan2
- SPTB | c.3276C>T p.S1092= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as COSV67635379; called by muse, mutect2, varscan2
- TUT7 | c.3399T>C p.L1133= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV99463784; called by muse, mutect2, varscan2
